Somatic mutation profile of tumor specimen MMRF_1965_1_BM_CD138pos (aliquot MMRF_1965_1_BM_CD138pos_T1_KBS5U_L07257) from MMRF case MMRF_1965, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.4 years (22,053 days).
Specimen MMRF_1965_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79d1e333-e9ad-4979-a527-e3f5e01aefaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1965_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1965_1_PB_CD3pos_C5_KBS5U_L07259; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb73dd99-090d-480e-9839-629513dbcbe4

The open-access MAF lists 901 somatic variants for this specimen: 288 protein-altering or splice-affecting, 124 silent, 489 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 249, 3'UTR 245, Silent 124, Intron 120, 5'UTR 63, Nonsense Mutation 29, 5'Flank 24, 3'Flank 21, RNA 16, Splice Region 5, Frame Shift Del 2, Splice Site 1.

Variants (750 of 901; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.6115G>A p.E2039K | Missense Mutation (SNP) | VAF 244/358 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs864622251, CM094668, COSV53740536, COSV53772321; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 58/286 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 30/284 reads (11%) | catalogued as rs63750832, CM990715, COSV52279974, COSV99316104; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC131160.1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV100226150, COSV57701900; called by muse, mutect2, varscan2
- ADAM17 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV60397370; called by mutect2, varscan2
- ADGRB3 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 189/424 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as rs776701796; called by muse, mutect2, varscan2
- AGGF1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1238912433; called by muse, mutect2, varscan2
- ANO9 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); catalogued as rs777434943; called by muse, mutect2, varscan2
- ARFGEF3 | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as rs952834056, COSV52457413; called by muse, mutect2, varscan2
- ARHGAP21 | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11014178; called by muse, mutect2, varscan2
- ARSI | c.119C>G p.S40W | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs373063727; called by muse, mutect2, varscan2
- ATM | c.8683G>A p.E2895K | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53734559, COSV99069695; called by muse, mutect2, varscan2
- BAIAP2L1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.038); catalogued as COSV99134117; called by muse, mutect2, varscan2
- BAIAP3 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs371035129; called by muse, mutect2, varscan2
- BAZ2A | c.4310C>T p.S1437L | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs996772120; called by muse, mutect2, varscan2
- BCLAF1 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 51/101 reads (50%) | catalogued as rs754139777, COSV100786791; called by muse, mutect2, varscan2
- BCLAF1 | c.1605C>G p.I535M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.973); catalogued as rs748242109; called by muse, mutect2, varscan2
- BTBD9 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV100023012; called by muse, mutect2, varscan2
- C1orf112 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 127/127 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as COSV53683440; called by muse, mutect2, varscan2
- C6orf141 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV64586169; called by muse, mutect2, varscan2
- CASP14 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs140739098; called by muse, mutect2, varscan2
- CCDC136 | c.2448G>C p.K816N | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV99922874; called by muse, mutect2
- CDK12 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.833); catalogued as COSV71000091; called by muse, mutect2, varscan2
- COL14A1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1381094258; called by muse, mutect2
- COPB1 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 55/112 reads (49%) | catalogued as rs1053617255; called by muse, mutect2, varscan2
- CORO1A | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs1483959987; called by muse, mutect2, varscan2
- DDX39B | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100385435, COSV58214075; called by muse, mutect2, varscan2
- DGUOK | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 103/208 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV51205286; called by muse, mutect2, varscan2
- DNAH6 | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1304818688; called by muse, mutect2, varscan2
- DNM2 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs778020908, COSV58968501; called by muse, varscan2
- DQX1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1384481063; called by muse, mutect2, varscan2
- DSC3 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 143/324 reads (44%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV64574528; called by muse, mutect2, varscan2
- DYSF | c.5773del p.L1925Cfs*41 | Frame Shift Del (DEL) | VAF 31/78 reads (40%) | catalogued as COSV99248253; called by mutect2, pindel, varscan2
- EP300 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 94/181 reads (52%) | catalogued as COSV54326876; called by muse, mutect2, varscan2
- EXOC3 | c.2017C>G p.L673V | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as COSV59265894; called by muse, mutect2, varscan2
- FAM120A | c.1798C>G p.L600V | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as rs758792503; called by muse, mutect2, varscan2
- FANCC | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100002868, COSV56658258; called by muse, mutect2, varscan2
- FCHO1 | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.262); catalogued as rs769532665; called by muse, mutect2, varscan2
- FCMR | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 193/394 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373086444; called by muse, mutect2, varscan2
- FYB1 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV60946000; called by muse, mutect2, varscan2
- FYB2 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV58586023; called by muse, mutect2
- GALR1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.421); catalogued as COSV100231846; called by muse, mutect2, varscan2
- GALR2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs766251513; called by muse, mutect2, varscan2
- GCOM1 | c.817A>G p.S273G | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as rs1374418659; called by muse, mutect2, varscan2
- GLA | c.708G>C p.W236C | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869312386, CM960769, COSV54509978; called by muse, mutect2
- GMDS | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66413778; called by muse, mutect2, varscan2
- GRIPAP1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1569520273; called by muse, mutect2, varscan2
- GTF3C6 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as rs1448585962; called by muse, mutect2, varscan2
- HMGB2 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.378); catalogued as COSV99632579; called by muse, mutect2, varscan2
- IGKJ5 | c.11T>A p.F4Y | Missense Mutation (SNP) | VAF 105/105 reads (100%) | catalogued as rs140799895; called by muse, varscan2
- IGLV3-1 | c.204A>C p.Q68H | Missense Mutation (SNP) | VAF 80/80 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs376783127; called by muse, varscan2
- IL27RA | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV99652342; called by muse, mutect2, varscan2
- KATNIP | c.3236A>G p.N1079S | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560393620, COSV55193461; called by muse, mutect2, varscan2
- KCNIP4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV62853124; called by muse, mutect2
- KRT23 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as rs758409000, COSV52929270; called by muse, mutect2, varscan2
- KRTAP12-4 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs781859959, COSV59973816; called by muse, mutect2, varscan2
- LAMA2 | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.084); catalogued as COSV70343705; called by muse, mutect2, varscan2
- LAMA2 | c.7508G>A p.R2503K | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70345964; called by muse, mutect2, varscan2
- LPL | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV60932515; called by muse, mutect2
- MARCHF9 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV56984654; called by muse, mutect2, varscan2
- MCTP2 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59150487; called by muse, mutect2, varscan2
- MRPL28 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.156); catalogued as rs1567320172; called by muse, mutect2
- MUC17 | c.9077C>T p.S3026F | Missense Mutation (SNP) | VAF 55/481 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); catalogued as rs1220192316, COSV60305379; called by muse, mutect2, varscan2
- MXRA8 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as rs373508903; called by muse, mutect2, varscan2
- MYH14 | c.4174G>C p.E1392Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV99222634; called by muse, mutect2, varscan2
- MYH2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs767416022, COSV55445528; called by muse, mutect2, varscan2
- MYH3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs1396728749, COSV56870002; called by muse, mutect2, varscan2
- NAV1 | c.5590G>A p.D1864N | Missense Mutation (SNP) | VAF 95/918 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV55222246; called by muse, mutect2, varscan2
- NCKAP5L | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1565588122, COSV60134941; called by muse, mutect2, varscan2
- NPTX1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 100/103 reads (97%) | catalogued as COSV60775721; called by muse, mutect2, varscan2
- OBSCN | c.15502G>A p.E5168K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546943719; called by muse, mutect2, varscan2
- OR4S2 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs764592618, COSV100412864, COSV56748527; called by muse, mutect2, varscan2
- OR8G1 | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.12); catalogued as COSV58379975; called by muse, mutect2, varscan2
- PCDHA7 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 104/136 reads (76%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.846); catalogued as COSV65342015; called by mutect2, varscan2
- PCDHGA10 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); catalogued as COSV53968380; called by muse, mutect2, varscan2
- PCDHGA5 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.006); catalogued as COSV99537264; called by muse, mutect2, varscan2
- PCDHGA7 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.029); catalogued as rs755956919, COSV54039160; called by muse, mutect2, varscan2
- PHACTR2 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV59854458, COSV59859974, COSV99992009; called by muse, mutect2, varscan2
- PLCB1 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs759604666, COSV62060310; called by muse, mutect2, varscan2
- PLEKHG6 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs1413704967, COSV99164972; called by muse, mutect2, varscan2
- PNMA8B | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 147/283 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV66537275; called by muse, mutect2, varscan2
- POLR2E | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 95/197 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53125521; called by muse, mutect2, varscan2
- PPP1R12A | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1189002862, COSV54106711; called by muse, mutect2, varscan2
- PRDM1 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 36/175 reads (21%) | catalogued as COSV64846690, COSV64847475; called by muse, mutect2, varscan2
- PRDM6 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as rs910507076; called by muse, mutect2, varscan2
- RASA4B | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1293574147; called by muse, mutect2, varscan2
- RNLS | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV59291566; called by muse, mutect2, varscan2
- ROBO2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 91/171 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV59940690; called by muse, mutect2, varscan2
- RPL7 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs773722193; called by muse, mutect2, varscan2
- RPS19 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as CM167143; called by muse, mutect2, varscan2
- RPTOR | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs372641715, COSV60809086; called by muse, varscan2
- RYR2 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63675798; called by muse, mutect2, varscan2
- SAMD4A | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 93/197 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); catalogued as rs1227045080, COSV51876396; called by muse, mutect2, varscan2
- SCYL1 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs762912713; called by muse, mutect2, varscan2
- SDK1 | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV67387536; called by muse, mutect2, varscan2
- SIPA1 | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs945236130, COSV63139591; called by muse, mutect2, varscan2
- SLC25A22 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs1332876414; called by muse, mutect2, varscan2
- SLC26A4 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767477168; called by muse, mutect2, varscan2
- SLC2A10 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148324236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A10 | c.1505G>C p.R502T (on ENST00000446997 / NM_001354461.2; = p.R472T on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV55797795; called by muse, mutect2, varscan2
- SMC4 | c.3658G>T p.E1220* | Nonsense Mutation (SNP) | VAF 86/193 reads (45%) | catalogued as COSV59088199; called by muse, varscan2
- SP140 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as rs1460200631; called by muse, mutect2, varscan2
- STAG1 | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99366368; called by muse, mutect2, varscan2
- STK36 | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs200344143; called by muse, mutect2, varscan2
- STRBP | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 66/141 reads (47%) | catalogued as COSV62118189; called by muse, mutect2, varscan2
- STXBP3 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as rs1394646096; called by muse, mutect2, varscan2
- SYBU | c.224G>A p.C75Y (on ENST00000276646 / NM_001099754.2; = p.C74Y on NM_017786.6) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs368359388; called by muse, mutect2, varscan2
- TAF7 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs367564007; called by muse, mutect2, varscan2
- TBL1XR1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV101467814; called by muse, mutect2, varscan2
- TCF20 | c.2046G>C p.Q682H | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs1258925350; called by mutect2, varscan2
- TENM2 | c.3034G>A p.E1012K (on ENST00000518659 / NM_001122679.2; = p.E780K on NM_001080428.3) | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1368396537; called by muse, mutect2, varscan2
- TLE3 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58166389; called by muse, mutect2
- TLN1 | c.5308G>T p.E1770* | Nonsense Mutation (SNP) | VAF 68/133 reads (51%) | catalogued as COSV59210721; called by muse, mutect2, varscan2
- TNRC6B | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100109548; called by muse, mutect2
- TOR2A | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV59122946; called by muse, mutect2, varscan2
- TRIML1 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60194308; called by muse, mutect2, varscan2
- TSC1 | c.2686C>T p.L896F | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs377132822, COSV53768413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPAN16 | c.451-6C>G | Splice Region (SNP) | VAF 4/30 reads (13%) | catalogued as rs368795124; called by muse, mutect2
- TTN | c.1954G>A p.E652K (on ENST00000591111; = p.E606K on NM_003319.4) | Missense Mutation (SNP) | VAF 61/147 reads (41%) | PolyPhen benign (0.003); catalogued as rs756924799, COSV60261974; called by muse, mutect2, varscan2
- UNC80 | c.5098C>A p.P1700T | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM160412; called by muse, mutect2, varscan2
- VSX2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56217473; called by muse, mutect2, varscan2
- ZBTB11 | c.1618C>G p.Q540E | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as COSV57244720; called by muse, mutect2, varscan2
- ZFPM1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100128299; called by muse, mutect2, varscan2
- ZNF366 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs762722295, COSV100574170; called by muse, mutect2, varscan2
- ZNF395 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765714526, COSV60429682; called by mutect2, varscan2
- ZNF420 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV58494123, COSV99077443; called by muse, mutect2, varscan2
- ZNF462 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV52948128; called by muse, mutect2, varscan2
- ZNF468 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 13/351 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1250696503; called by muse, mutect2
- ZNF488 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 143/325 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.087); catalogued as rs782380361; called by muse, mutect2, varscan2
- ZNF750 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 46/59 reads (78%) | catalogued as rs377565207, COSV53961393, COSV53961753; called by muse, mutect2, varscan2
- ZSCAN1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.301); catalogued as rs762191438; called by muse, mutect2, varscan2
- AASDHPPT | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 196/299 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM19 | c.2428C>T p.H810Y | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.10933C>G p.L3645V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADNP | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 115/243 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- AL645922.1 | c.3484G>A p.A1162T | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKIB1 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- BLMH | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2
- C11orf54 | c.658C>A p.P220T (on ENST00000331239; = p.P170T on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C20orf202 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- C2CD2 | c.7_23del p.M3Vfs*93 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by mutect2, varscan2
- CACNG1 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 146/345 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CADPS | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CBLC | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC77 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- CCDC88C | c.5426C>T p.S1809L | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDAN1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 90/190 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CEP162 | c.3766C>T p.Q1256* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- CHCHD7 | c.113C>T p.S38F (on ENST00000355315 / NM_001011671.3; = p.S50F on NM_024300.4) | Missense Mutation (SNP) | VAF 167/342 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- CLN6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLVS2 | c.207C>G p.F69L | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- CMAS | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CNTRL | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- COA1 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- COL22A1 | c.3740G>A p.R1247K | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CPEB3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRLF1 | c.438G>C p.K146N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- DCHS1 | c.9772C>G p.L3258V | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DDX19B | c.1305G>T p.K435N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- DENND1B | c.771C>T p.C257= | Splice Region (SNP) | VAF 22/304 reads (7%) | called by muse, mutect2
- DENND4B | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DENND5B | c.2940G>C p.M980I | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DMBT1 | c.7147G>A p.D2383N (on ENST00000338354 / NM_001377530.1; = p.D1626N on NM_004406.3) | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNM3 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK11 | c.424C>G p.H142D | Missense Mutation (SNP) | VAF 117/117 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DYNC2H1 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- EDNRA | c.1241A>G p.N414S | Missense Mutation (SNP) | VAF 76/415 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EXTL3 | c.1381C>A p.P461T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM193A | c.2950C>T p.H984Y | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.003); called by muse, mutect2
- FAM83H | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT2 | c.10222G>C p.E3408Q | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAXDC2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- FNDC1 | c.1856C>G p.S619C | Missense Mutation (SNP) | VAF 92/189 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- FUBP3 | c.459_461del p.F154del | In Frame Del (DEL) | VAF 34/83 reads (41%) | called by mutect2, pindel, varscan2
- FXR2 | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- GALNT3 | c.1418G>C p.R473T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GIMAP5 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 110/222 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLI3 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- GOLGA4 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GUCY1A1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HEATR1 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2
- HELZ2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- HERPUD1 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 100/194 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- HMCN1 | c.4792G>C p.D1598H | Missense Mutation (SNP) | VAF 34/375 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2
- IDE | c.1668G>C p.M556I | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- IGHV3-53 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 132/355 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- INO80B | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- IRF2BP2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.29); called by muse, mutect2
- KANSL2 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.531); called by muse, mutect2
- KAT6B | c.5398C>T p.Q1800* | Nonsense Mutation (SNP) | VAF 127/251 reads (51%) | called by muse, mutect2, varscan2
- KCNK17 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- KDM3B | c.5206-1G>C p.X1736_splice | Splice Site (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- KLHL3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- KRT75 | c.711C>T p.V237= | Splice Region (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- LAMA5 | c.10793C>T p.S3598L | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRFN1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MDGA2 | c.2917G>C p.E973Q (on ENST00000399232 / NM_001113498.2; = p.E675Q on NM_182830.4) | Missense Mutation (SNP) | VAF 114/206 reads (55%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, varscan2
- MDN1 | c.15703G>C p.E5235Q | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.255); called by muse, mutect2
- MOGAT3 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MTMR6 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MUC17 | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 37/777 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2
- MUC20 | c.1931C>G p.T644R | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MUSK | c.2557C>T p.H853Y | Missense Mutation (SNP) | VAF 152/312 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.074); called by muse, varscan2
- MYG1 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- MYO10 | c.4363G>A p.E1455K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- NAV3 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKAPL | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- NLRP4 | c.2008C>G p.Q670E | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NR4A2 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRG2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- NRXN2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- NUAK2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAN2 | c.8T>G p.F3C | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCDHGB6 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- PELI1 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 48/217 reads (22%) | called by muse, mutect2, varscan2
- PHAX | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 53/102 reads (52%) | called by muse, mutect2, varscan2
- PHPT1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PLEC | c.2589G>A p.Q863= (on ENST00000322810 / NM_201380.4; = p.Q753= on NM_000445.5) | Splice Region (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- PNLIPRP2 | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PROS1 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- PRSS12 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSMC1 | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PWWP2A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.012); called by muse, varscan2
- PXDC1 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 95/188 reads (51%) | called by muse, mutect2, varscan2
- RANBP10 | c.1832C>G p.S611C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RASA4 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RASAL1 | c.1194C>G p.F398L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- RBM4 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 133/272 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- RHOG | c.-66C>A | Splice Region (SNP) | VAF 68/127 reads (54%) | called by muse, mutect2, varscan2
- RHOV | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- RICTOR | c.4646T>C p.I1549T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.116); called by muse, mutect2
- RNF180 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ROCK1 | c.1566G>T p.Q522H | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ROPN1 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RP2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 55/55 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SALL4 | c.2080G>C p.E694Q | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SAP30 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SARAF | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 81/82 reads (99%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.6); called by muse, mutect2
- SBK2 | c.1015G>C p.V339L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDK2 | c.5906G>T p.S1969I | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINH1 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | called by muse, mutect2, varscan2
- SHBG | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- SLC12A8 | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 157/341 reads (46%) | called by muse, varscan2
- SLC25A16 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SLC25A3 | c.323C>A p.S108* (on ENST00000228318 / NM_005888.3; = p.S107* on NM_002635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 67/116 reads (58%) | called by muse, mutect2, varscan2
- SLC25A38 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC7A5 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by muse, mutect2
- SMARCD3 | c.559G>A p.E187K (on ENST00000262188 / NM_001003801.2; = p.E174K on NM_003078.4) | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SNRPF | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SOGA3 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SP140L | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SP2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 134/247 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2
- SRP72 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- SRRM4 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRSF4 | c.1005G>T p.R335S | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SSR3 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- STX19 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 132/238 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STXBP5 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TCP1 | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TESK2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TGS1 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 139/285 reads (49%) | called by muse, mutect2, varscan2
- TMCC2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- TNFRSF11A | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- TRAPPC8 | c.2546C>T p.S849F | Missense Mutation (SNP) | VAF 10/344 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2
- TRIM47 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TSHZ1 | c.1103C>T p.A368V (on ENST00000580243 / NM_001308210.2; = p.A323V on NM_005786.6) | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBB4B | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- TUT7 | c.2935C>G p.P979A | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBAP2L | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- UEVLD | c.1415G>C p.*472Sext*6 | Nonstop Mutation (SNP) | VAF 135/304 reads (44%) | called by muse, mutect2, varscan2
- UPP2 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); called by muse, mutect2
- VANGL1 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 183/183 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VLDLR | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDFY3 | c.5752G>C p.D1918H | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- XIRP2 | c.2296G>C p.D766H (on ENST00000628543; = p.D941H on NM_152381.6) | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ZC3H7B | c.2683C>T p.L895F | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZMYM4 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF160 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZNF18 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF195 | c.1751G>T p.G584V (on ENST00000399602 / NM_001130520.3; = p.G512V on NM_007152.5) | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF214 | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF366 | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZNF415 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 47/235 reads (20%) | called by muse, mutect2, varscan2
- ZNF570 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ZNF622 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF780B | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- ZNF827 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 86/172 reads (50%) | called by muse, mutect2, varscan2
- ZWILCH | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- ABCA2 | c.5859C>T p.T1953= (on ENST00000614293; = p.T1923= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/103 reads (54%) | called by muse, varscan2
- AC004593.2 | c.951G>A p.G317= | Silent (SNP) | VAF 51/92 reads (55%) | called by muse, mutect2, varscan2
- ACO1 | c.1713G>A p.E571= | Silent (SNP) | VAF 73/164 reads (45%) | called by muse, mutect2, varscan2
- ACOT4 | c.282G>A p.L94= | Silent (SNP) | VAF 65/140 reads (46%) | catalogued as rs1261487386; called by muse, mutect2, varscan2
- ADAMTS12 | c.2190A>G p.R730= | Silent (SNP) | VAF 17/306 reads (6%) | called by muse, mutect2
- AHNAK | c.7845C>T p.I2615= | Silent (SNP) | VAF 140/286 reads (49%) | catalogued as rs1399153372, COSV57210697; called by muse, mutect2, varscan2
- AK2 | c.9C>T p.P3= | Silent (SNP) | VAF 35/60 reads (58%) | called by muse, mutect2, varscan2
- AKAP13 | c.6333C>T p.F2111= (on ENST00000394518 / NM_007200.5; = p.F2115= on NM_006738.6) | Silent (SNP) | VAF 101/206 reads (49%) | called by muse, mutect2, varscan2
- ANO3 | c.1668C>T p.F556= | Silent (SNP) | VAF 31/240 reads (13%) | catalogued as COSV56803440; called by muse, mutect2, varscan2
- AP1B1 | c.612C>A p.I204= | Silent (SNP) | VAF 43/43 reads (100%) | called by muse, mutect2, varscan2
- BTNL2 | c.54C>T p.F18= | Silent (SNP) | VAF 164/338 reads (49%) | catalogued as COSV66630357; called by muse, mutect2, varscan2
- C19orf84 | c.84G>A p.A28= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs1047683939; called by muse, mutect2, varscan2
- C1orf131 | c.102G>A p.Q34= | Silent (SNP) | VAF 252/253 reads (100%) | called by muse, mutect2, varscan2
- CAND2 | c.516C>T p.F172= (on ENST00000456430 / NM_001162499.2; = p.F79= on NM_012298.3) | Silent (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- CDH1 | c.2607C>T p.F869= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- CDRT1 | c.1135C>T p.L379= | Silent (SNP) | VAF 64/161 reads (40%) | called by muse, mutect2, varscan2
- CEP135 | c.2238G>A p.K746= | Silent (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- CFAP92 | c.3030C>G p.L1010= | Silent (SNP) | VAF 147/346 reads (42%) | called by muse, mutect2, varscan2
- CNOT1 | c.5550G>A p.E1850= | Silent (SNP) | VAF 54/108 reads (50%) | called by muse, mutect2, varscan2
- CRAMP1 | c.285G>A p.R95= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs763376463; called by muse, mutect2, varscan2
- CRAMP1 | c.1167G>A p.P389= | Silent (SNP) | VAF 81/158 reads (51%) | catalogued as rs777275882, COSV51961913; called by muse, mutect2, varscan2
- CSMD3 | c.2523C>T p.I841= (on ENST00000297405 / NM_001363185.1; = p.I737= on NM_052900.3) | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV52112456; called by muse, mutect2, varscan2
- CUX2 | c.3489G>C p.L1163= | Silent (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- CXCL3 | c.114C>T p.V38= | Silent (SNP) | VAF 53/115 reads (46%) | called by muse, mutect2, varscan2
- DAPK1 | c.388C>T p.L130= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV63791995; called by muse, mutect2, varscan2
- DNAH7 | c.9738G>A p.E3246= | Silent (SNP) | VAF 62/133 reads (47%) | catalogued as COSV56771100; called by muse, mutect2, varscan2
- DNAH7 | c.6690C>T p.I2230= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV56759913, COSV56760511; called by mutect2, varscan2
- DNAJC13 | c.6387G>A p.L2129= | Silent (SNP) | VAF 75/154 reads (49%) | called by muse, varscan2
- DOCK5 | c.4254C>T p.I1418= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- EMD | c.108G>A p.K36= | Silent (SNP) | VAF 63/64 reads (98%) | catalogued as rs1057521050; ClinVar: likely benign; called by muse, mutect2, varscan2
- EXOC5 | c.24C>T p.F8= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs1455512459; called by muse, varscan2
- FAM166A | c.222G>A p.P74= | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as rs761312533; called by muse, mutect2, varscan2
- FAM83H | c.1236C>T p.F412= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs1554623221; called by muse, mutect2, varscan2
- FCRLA | c.72C>T p.L24= (on ENST00000367959; = p.L7= on NM_032738.4) | Silent (SNP) | VAF 37/257 reads (14%) | catalogued as COSV52687599; called by muse, mutect2, varscan2
- FERMT1 | c.444G>A p.K148= | Silent (SNP) | VAF 87/180 reads (48%) | catalogued as COSV99451408; called by muse, mutect2, varscan2
- FLRT2 | c.414G>A p.L138= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- FOXH1 | c.342G>C p.L114= | Silent (SNP) | VAF 53/95 reads (56%) | called by muse, mutect2, varscan2
- FOXO6 | c.9G>A p.A3= | Silent (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- FOXP2 | c.795G>A p.E265= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100647426, COSV63481875; called by muse, mutect2
- GAMT | c.30C>T p.F10= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- GCC1 | c.138G>A p.L46= | Silent (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- GNL3L | c.1225C>T p.L409= | Silent (SNP) | VAF 89/89 reads (100%) | catalogued as rs1295483867; called by muse, mutect2, varscan2
- GPR139 | c.474G>A p.L158= | Silent (SNP) | VAF 64/127 reads (50%) | called by muse, mutect2, varscan2
- GSTZ1 | c.300T>C p.R100= | Silent (SNP) | VAF 75/139 reads (54%) | called by muse, mutect2, varscan2
- HIPK2 | c.1464C>T p.S488= | Silent (SNP) | VAF 82/186 reads (44%) | catalogued as rs144061745; called by muse, mutect2, varscan2
- HR | c.2871G>T p.L957= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- HRC | c.210G>A p.E70= | Silent (SNP) | VAF 88/200 reads (44%) | called by muse, mutect2, varscan2
- HSF2 | c.9G>A p.Q3= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs770227286; called by muse, mutect2, varscan2
- IGSF23 | c.578G>A p.*193= | Silent (SNP) | VAF 108/222 reads (49%) | catalogued as COSV68806833; called by muse, varscan2
- ITIH1 | c.2688A>G p.G896= | Silent (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- KIF26B | c.3210C>T p.I1070= | Silent (SNP) | VAF 26/460 reads (6%) | catalogued as rs1183890315; called by muse, mutect2
- KIF5A | c.1083G>A p.A361= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs528282741, COSV99673453; called by muse, mutect2, varscan2
- KRT6B | c.894G>A p.L298= | Silent (SNP) | VAF 91/197 reads (46%) | catalogued as COSV52883421; called by muse, mutect2, varscan2
- LEPR | c.2151C>T p.I717= | Silent (SNP) | VAF 11/194 reads (6%) | called by muse, mutect2
- LTB4R2 | c.456C>T p.L152= (on ENST00000528054; = p.L121= on NM_019839.5) | Silent (SNP) | VAF 51/90 reads (57%) | called by muse, mutect2, varscan2
- MAIP1 | c.672G>A p.L224= | Silent (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- MFHAS1 | c.36G>A p.A12= | Silent (SNP) | VAF 19/19 reads (100%) | called by muse, mutect2, varscan2
- MPP4 | c.96G>A p.L32= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV59633929; called by muse, mutect2, varscan2
- MRPL32 | c.411C>T p.I137= | Silent (SNP) | VAF 113/244 reads (46%) | catalogued as COSV56239124; called by muse, varscan2
- MRPL34 | c.243C>T p.R81= | Silent (SNP) | VAF 17/42 reads (40%) | called by mutect2, varscan2
- MTHFSD | c.726C>T p.L242= (on ENST00000360900 / NM_001159377.2; = p.L241= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- MUL1 | c.1038G>A p.V346= | Silent (SNP) | VAF 52/123 reads (42%) | catalogued as COSV51642566; called by muse, mutect2, varscan2
- MYH14 | c.1800G>A p.A600= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV99223062, COSV99224573; called by muse, mutect2, varscan2
- MYLK3 | c.1800G>A p.R600= | Silent (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- MYO3A | c.2184C>G p.S728= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- MYRF | c.2064G>A p.L688= (on ENST00000278836 / NM_001127392.3; = p.L679= on NM_013279.4) | Silent (SNP) | VAF 62/116 reads (53%) | catalogued as rs1369751470; called by muse, varscan2
- NCF4 | c.291G>A p.V97= | Silent (SNP) | VAF 16/429 reads (4%) | catalogued as rs1480761109; called by muse, mutect2
- NHEJ1 | c.891C>A p.L297= | Silent (SNP) | VAF 93/212 reads (44%) | called by muse, mutect2, varscan2
- NHSL1 | c.4362G>A p.Q1454= | Silent (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- NUMBL | c.1650G>A p.G550= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs1255932673; called by muse, mutect2, varscan2
- OCA2 | c.1779C>T p.F593= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2
- PAPPA | c.324C>T p.L108= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- PID1 | c.198C>T p.V66= (on ENST00000354069 / NM_001330156.1; = p.V64= on NM_017933.5) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1182386672, COSV62483465; called by muse, mutect2, varscan2
- PIGB | c.1008G>A p.K336= | Silent (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- PIGQ | c.1683G>A p.L561= (on ENST00000026218 / NM_148920.3; = p.*582= on NM_004204.5) | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV50312607, COSV99215579; called by muse, mutect2
- PIM1 | c.288G>A p.V96= | Silent (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
- PRDM8 | c.2025C>T p.F675= | Silent (SNP) | VAF 170/318 reads (53%) | called by muse, mutect2, varscan2
- PRORP | c.177G>A p.T59= | Silent (SNP) | VAF 12/277 reads (4%) | catalogued as COSV51621210; called by muse, mutect2
- PROSER2 | c.1056G>A p.L352= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- PRPH | c.336C>T p.I112= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as rs754630788; called by muse, mutect2, varscan2
- PWWP2A | c.393G>A p.E131= | Silent (SNP) | VAF 66/135 reads (49%) | called by muse, varscan2
- RANBP3L | c.63G>A p.L21= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs1424938044; called by muse, mutect2, varscan2
- RELB | c.840G>A p.Q280= | Silent (SNP) | VAF 65/161 reads (40%) | called by muse, mutect2, varscan2
- RIBC1 | c.459G>A p.L153= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- RNF19B | c.303C>T p.F101= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- SCN10A | c.3906C>G p.L1302= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as COSV71861461; called by muse, mutect2
- SFRP4 | c.687C>T p.P229= | Silent (SNP) | VAF 70/133 reads (53%) | called by muse, mutect2, varscan2
- SKAP2 | c.132G>A p.K44= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- SLC33A1 | c.291C>T p.L97= | Silent (SNP) | VAF 39/138 reads (28%) | called by muse, mutect2, varscan2
- SLC43A3 | c.1170C>T p.L390= | Silent (SNP) | VAF 31/62 reads (50%) | called by muse, varscan2
- SLC5A6 | c.1707C>T p.L569= | Silent (SNP) | VAF 63/131 reads (48%) | catalogued as COSV100143211; called by muse, mutect2, varscan2
- SLC7A7 | c.1290C>T p.F430= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as rs368164901; called by muse, mutect2, varscan2
- SLCO1C1 | c.51G>A p.V17= | Silent (SNP) | VAF 141/326 reads (43%) | catalogued as rs377286815, COSV56879743; called by muse, mutect2, varscan2
- SNX25 | c.1659C>T p.L553= | Silent (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- SPARCL1 | c.1233G>A p.E411= | Silent (SNP) | VAF 112/233 reads (48%) | catalogued as COSV56802730; called by muse, mutect2, varscan2
- SPAST | c.183C>T p.F61= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV100188460, COSV59515052; called by muse, mutect2, varscan2
- SPATA48 | c.1266G>C p.V422= | Silent (SNP) | VAF 119/261 reads (46%) | called by muse, mutect2, varscan2
- SRMS | c.1455A>G p.R485= | Silent (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- SRPK2 | c.66G>A p.P22= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1270208415; called by muse, mutect2, varscan2
- STARD9 | c.3360G>C p.L1120= | Silent (SNP) | VAF 130/271 reads (48%) | called by muse, mutect2, varscan2
- SYT4 | c.516C>T p.V172= | Silent (SNP) | VAF 72/173 reads (42%) | called by muse, mutect2, varscan2
- TGIF1 | c.579C>T p.L193= (on ENST00000330513 / NM_001374396.1; = p.L213= on NM_003244.4) | Silent (SNP) | VAF 155/338 reads (46%) | catalogued as rs1256384293; called by muse, mutect2, varscan2
- TLK1 | c.1725C>T p.L575= | Silent (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- TMEM200C | c.516C>T p.I172= | Silent (SNP) | VAF 49/248 reads (20%) | catalogued as COSV67309285; called by muse, mutect2, varscan2
- TMEM231 | c.732G>T p.V244= (on ENST00000258173 / NM_001077418.3; = p.V273= on NM_001077416.2) | Silent (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- TOMM34 | c.762C>G p.L254= | Silent (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- TRIO | c.3819G>A p.V1273= | Silent (SNP) | VAF 57/127 reads (45%) | called by muse, mutect2, varscan2
- TSPYL5 | c.132C>T p.L44= | Silent (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- TTC28 | c.5704C>T p.L1902= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as rs181049098; called by muse, mutect2, varscan2
- TUBA4A | c.276C>G p.L92= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99944676, COSV99944715; called by muse, mutect2, varscan2
- TUBA4B | c.162C>A p.I54= | Silent (SNP) | VAF 104/203 reads (51%) | called by muse, mutect2, varscan2
- TXLNA | c.213C>T p.V71= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as rs769339074; called by muse, mutect2, varscan2
- TXNRD1 | c.358C>T p.L120= (on ENST00000525566 / NM_001093771.3; = p.L22= on NM_003330.4) | Silent (SNP) | VAF 70/148 reads (47%) | called by muse, varscan2
- USP19 | c.1210C>T p.L404= | Silent (SNP) | VAF 104/213 reads (49%) | catalogued as rs775020572; called by muse, mutect2, varscan2
- USP20 | c.1872C>T p.I624= | Silent (SNP) | VAF 204/392 reads (52%) | called by muse, varscan2
- VAX2 | c.387C>T p.G129= | Silent (SNP) | VAF 54/94 reads (57%) | called by muse, mutect2, varscan2
- VWA5B2 | c.1068C>G p.L356= | Silent (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- WDR36 | c.105G>A p.L35= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV72411354; called by muse, mutect2, varscan2
- WNK4 | c.1182G>A p.P394= | Silent (SNP) | VAF 70/144 reads (49%) | catalogued as rs777411138, COSV55906084; called by muse, mutect2, varscan2
- WWTR1 | c.723G>A p.Q241= | Silent (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- ZFP64 | c.900G>A p.G300= | Silent (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- ZNF18 | c.1503C>T p.F501= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV59552863; called by muse, mutect2
- ZNF397 | c.159C>T p.F53= | Silent (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- ZNF827 | c.2979G>T p.G993= | Silent (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2, varscan2
- ABCC8 | c.1817+54C>A | Intron (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- AC004951.3 | n.694G>A | RNA (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- AC007064.4 | n.185A>G | RNA (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- AC009093.9 | n.61C>T | RNA (SNP) | VAF 33/57 reads (58%) | catalogued as rs1488453932; called by muse, mutect2, varscan2
- AC022415.2 | c.*1348G>A | 3'UTR (SNP) | VAF 21/342 reads (6%) | called by muse, mutect2
- AC024651.2 | chr15:97874427 G>A | 5'Flank (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- ACSS2 | c.643+56C>G | Intron (SNP) | VAF 4/54 reads (7%) | catalogued as rs890790993; called by muse, mutect2
- ACTR3C | c.*38+493C>T | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ADAMTS5 | c.*5743G>A | 3'UTR (SNP) | VAF 43/106 reads (41%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.-228G>A | 5'UTR (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- ADCY1 | c.*8814G>C | 3'UTR (SNP) | VAF 43/151 reads (28%) | called by muse, mutect2, varscan2
- ADGRB3 | c.*82G>A | 3'UTR (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:62071998 A>T | 3'Flank (SNP) | VAF 92/197 reads (47%) | catalogued as rs1359063028; called by muse, mutect2, varscan2
- ADNP2 | c.*1393C>T | 3'UTR (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- AGO1 | c.*4422C>G | 3'UTR (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- AHI1 | chr6:135497928 G>A | 5'Flank (SNP) | VAF 20/39 reads (51%) | catalogued as rs984661576; called by muse, mutect2, varscan2
- AIFM1 | c.968-63C>G | Intron (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- AKAP9 | chr7:91940922 T>C | 5'Flank (SNP) | VAF 59/122 reads (48%) | called by muse, varscan2
- ALDH1L2 | c.*3893T>G | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- ALKBH5 | c.-10C>T | 5'UTR (SNP) | VAF 18/29 reads (62%) | catalogued as rs751172747; called by muse, mutect2, varscan2
- ANAPC15 | chr11:72106699 G>C | 3'Flank (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2
- ANK3 | c.2615-1716C>G | Intron (SNP) | VAF 16/81 reads (20%) | called by mutect2, varscan2
- ANKFY1 | c.-27G>A | 5'UTR (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- ANKRD13B | c.250+50C>T | Intron (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- ANKRD31 | c.-171C>T | 5'UTR (SNP) | VAF 28/51 reads (55%) | catalogued as COSV57164547; called by muse, mutect2, varscan2
- ANP32E | c.*2190C>T | 3'UTR (SNP) | VAF 24/203 reads (12%) | called by muse, mutect2, varscan2
- ANTXR2 | c.*5524C>T | 3'UTR (SNP) | VAF 25/68 reads (37%) | catalogued as rs927201999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1B1 | c.*206C>G | 3'UTR (SNP) | VAF 78/81 reads (96%) | called by muse, mutect2, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 34/61 reads (56%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- APBB2 | c.*3358G>A | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- APEH | c.-24C>T | 5'UTR (SNP) | VAF 5/63 reads (8%) | catalogued as rs1302881634; called by muse, mutect2
- APPL1 | c.*782C>T | 3'UTR (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.*2396G>A | 3'UTR (SNP) | VAF 7/64 reads (11%) | catalogued as rs1241228341; called by muse, mutect2, varscan2
- ARHGAP6 | c.589-11175C>T | Intron (SNP) | VAF 141/141 reads (100%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.97-1335G>A | Intron (SNP) | VAF 61/296 reads (21%) | called by muse, mutect2, varscan2
- ARID1B | c.2841-176G>C | Intron (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- ARL17B | c.*242C>T | 3'UTR (SNP) | VAF 57/306 reads (19%) | called by muse, mutect2, varscan2
- ASB2 | c.-92G>A | 5'UTR (SNP) | VAF 61/125 reads (49%) | called by muse, mutect2, varscan2
- ASGR2 | c.-60C>T | 5'UTR (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- ASIC1 | c.559-199G>T | Intron (SNP) | VAF 45/178 reads (25%) | called by muse, varscan2
- ASPH | c.-107G>A | 5'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- ATM | c.*2215C>T | 3'UTR (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- ATXN1 | c.*3998C>A | 3'UTR (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- BACE1 | c.*2404G>C | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- BCL11A | chr2:60452622 C>G | 3'Flank (SNP) | VAF 4/86 reads (5%) | catalogued as COSV59633073; called by muse, mutect2
- BCL7A | c.*999G>A | 3'UTR (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2, varscan2
- BORCS7 | c.*996C>G | 3'UTR (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- BRSK2 | c.*938G>C | 3'UTR (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- BRSK2 | c.*1301G>A | 3'UTR (SNP) | VAF 76/152 reads (50%) | called by muse, mutect2
- BTBD19 | c.-29C>T | 5'UTR (SNP) | VAF 74/137 reads (54%) | called by muse, mutect2, varscan2
- BZW1 | c.-10-518G>C | Intron (SNP) | VAF 73/141 reads (52%) | called by muse, mutect2, varscan2
- CALM2 | c.3+11C>A | Intron (SNP) | VAF 89/173 reads (51%) | called by muse, varscan2
- CAMK1D | c.*2424G>A | 3'UTR (SNP) | VAF 44/79 reads (56%) | catalogued as rs545803666; called by muse, mutect2, varscan2
- CAMK2A | c.*1290G>T | 3'UTR (SNP) | VAF 75/153 reads (49%) | called by muse, mutect2, varscan2
- CAMK2A | c.*970G>C | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- CAMK4 | c.*7608G>C | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- CAPN7 | c.-177C>T | 5'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- CAST | chr5:96662273 del G | 5'Flank (DEL) | VAF 26/59 reads (44%) | called by mutect2, pindel, varscan2
- CBL | c.*3138C>G | 3'UTR (SNP) | VAF 42/131 reads (32%) | called by muse, mutect2, varscan2
- CCDC62 | c.*334G>C | 3'UTR (SNP) | VAF 66/140 reads (47%) | called by muse, mutect2, varscan2
- CCND2 | c.-250G>A | 5'UTR (SNP) | VAF 55/98 reads (56%) | catalogued as rs956074804; called by muse, mutect2, varscan2
- CCR7 | c.*723C>T | 3'UTR (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- CCSER2 | c.*3830G>A | 3'UTR (SNP) | VAF 46/87 reads (53%) | called by muse, mutect2, varscan2
- CDC42BPA | c.*338G>C | 3'UTR (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- CENPL | c.*224C>G | 3'UTR (SNP) | VAF 95/816 reads (12%) | called by muse, mutect2, varscan2
- CENPP | c.*5566C>G | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- CEP120 | c.-182G>A | 5'UTR (SNP) | VAF 43/78 reads (55%) | catalogued as rs1017488532; called by muse, mutect2, varscan2
- CEP128 | c.*402C>T | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- CEP192 | c.4257+69C>G | Intron (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.279G>C | RNA (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- CHD2 | c.62+125G>A | Intron (SNP) | VAF 69/127 reads (54%) | catalogued as rs531333338; called by muse, mutect2, varscan2
- CHORDC1 | c.493-1536C>T | Intron (SNP) | VAF 39/51 reads (76%) | catalogued as rs1173022364; called by muse, mutect2, varscan2
- CHPF2 | c.-1091A>C | 5'UTR (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- CHRNA5 | c.-17C>T | 5'UTR (SNP) | VAF 24/42 reads (57%) | catalogued as COSV55138656; called by muse, mutect2, varscan2
- CIT | c.*975C>T | 3'UTR (SNP) | VAF 33/149 reads (22%) | catalogued as rs772668842; called by muse, mutect2, varscan2
- CLDN2 | c.*15G>A | 3'UTR (SNP) | VAF 80/83 reads (96%) | called by muse, mutect2, varscan2
- CLEC12A | c.10+60G>A | Intron (SNP) | VAF 92/220 reads (42%) | called by muse, mutect2, varscan2
- CLK1 | c.-1+242C>G | Intron (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- CLN3 | c.389-11C>T | Intron (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- CNNM1 | c.*942C>T | 3'UTR (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- CNTLN | c.*31G>A | 3'UTR (SNP) | VAF 195/392 reads (50%) | called by muse, mutect2, varscan2
- COG2 | c.72+145G>A | Intron (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- COPS3 | c.937-92G>A | Intron (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- CPNE4 | chr3:132037722 G>A | 5'Flank (SNP) | VAF 141/266 reads (53%) | called by muse, mutect2, varscan2
- CRACR2B | c.459-82C>T | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- CTDSP1 | c.657+128C>T | Intron (SNP) | VAF 9/16 reads (56%) | catalogued as rs1010459594; called by muse, mutect2, varscan2
- CTSA | c.*70C>G | 3'UTR (SNP) | VAF 73/147 reads (50%) | called by muse, mutect2, varscan2
- CTSZ | c.*93G>A | 3'UTR (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- CYP11B1 | c.955-38C>T | Intron (SNP) | VAF 130/235 reads (55%) | called by muse, mutect2, varscan2
- DAG1 | c.*746C>G | 3'UTR (SNP) | VAF 8/37 reads (22%) | catalogued as rs750547701; called by muse, mutect2, varscan2
- DBH | c.*160C>T | 3'UTR (SNP) | VAF 97/211 reads (46%) | called by muse, varscan2
- DCHS1 | c.*422C>T | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- DCP2 | c.*1594A>G | 3'UTR (SNP) | VAF 54/103 reads (52%) | called by muse, mutect2, varscan2
- DDX11 | c.2372+34G>C | Intron (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- DDX11 | c.2457+22G>C | Intron (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- DDX18 | c.1692+24G>A | Intron (SNP) | VAF 106/228 reads (46%) | catalogued as COSV54306076; called by muse, mutect2, varscan2
- DDX5 | chr17:64507270 C>T | 5'Flank (SNP) | VAF 5/13 reads (38%) | catalogued as COSV56748319; called by muse, mutect2, varscan2
- DENND10 | c.*413G>C | 3'UTR (SNP) | VAF 16/276 reads (6%) | called by muse, mutect2
- DENND2B | c.-25-15934G>C | Intron (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- DFFA | c.*1826G>A | 3'UTR (SNP) | VAF 66/117 reads (56%) | catalogued as rs1173686337; called by muse, mutect2, varscan2
- DGKQ | c.*138C>G | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- DHRS4L2 | c.666-1528G>C | Intron (SNP) | VAF 90/477 reads (19%) | catalogued as COSV58729290; called by muse, mutect2, varscan2
- DHX37 | c.3389-53G>C | Intron (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- DLGAP1 | c.2724+135G>A | Intron (SNP) | VAF 35/75 reads (47%) | catalogued as COSV100228690; called by muse, mutect2, varscan2
- DLL4 | c.*111C>G | 3'UTR (SNP) | VAF 103/205 reads (50%) | called by muse, mutect2, varscan2
- DLX2 | c.*504C>T | 3'UTR (SNP) | VAF 14/27 reads (52%) | catalogued as rs1411155484; called by muse, mutect2, varscan2
- DMXL1 | c.*1421A>G | 3'UTR (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- DNAJA1 | c.*271G>A | 3'UTR (SNP) | VAF 153/328 reads (47%) | called by muse, mutect2, varscan2
- DNAJB5 | c.*995C>T | 3'UTR (SNP) | VAF 13/61 reads (21%) | catalogued as rs1352279025; called by muse, mutect2, varscan2
- DNAJC19 | c.*277C>T | 3'UTR (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- DSEL | c.*3236G>A | 3'UTR (SNP) | VAF 39/63 reads (62%) | called by muse, mutect2, varscan2
- DSG4 | c.*3G>A | 3'UTR (SNP) | VAF 25/380 reads (7%) | called by muse, mutect2
- DUSP15 | c.12+321G>C | Intron (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- DVL3 | c.*2002A>G | 3'UTR (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.5978-111C>T | Intron (SNP) | VAF 10/23 reads (43%) | catalogued as rs1184345316; called by muse, mutect2
- EHD1 | c.*385G>A | 3'UTR (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- EIF3B | c.-29G>A | 5'UTR (SNP) | VAF 10/17 reads (59%) | catalogued as rs953999980; called by muse, mutect2, varscan2
- EIF4A1 | c.*471G>A | 3'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- ELFN2 | c.*2414G>A | 3'UTR (SNP) | VAF 68/138 reads (49%) | called by muse, varscan2
- ELFN2 | c.*2332G>A | 3'UTR (SNP) | VAF 61/120 reads (51%) | called by muse, varscan2
- EML2 | chr19:45642158 G>A | 5'Flank (SNP) | VAF 66/110 reads (60%) | called by muse, mutect2, varscan2
- ENPP3 | c.872+17_872+30delinsT | Intron (DEL) | VAF 23/135 reads (17%) | called by pindel, varscan2*
- EPHA7 | c.*1920T>C | 3'UTR (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- EPS8 | c.736+10C>T | Intron (SNP) | VAF 44/110 reads (40%) | catalogued as rs778388265; called by muse, mutect2, varscan2
- ERGIC3 | c.160-18G>A | Intron (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- ERMN | c.*2090C>G | 3'UTR (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- EXOC6B | c.1980+2165G>C | Intron (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2, varscan2
- EXT1 | c.-754C>T | 5'UTR (SNP) | VAF 71/148 reads (48%) | called by muse, mutect2, varscan2
- EYS | c.1766+23G>A | Intron (SNP) | VAF 99/209 reads (47%) | called by muse, mutect2, varscan2
- F13A1 | c.*1481T>G | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- FAM110D | c.*150G>A | 3'UTR (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- FAM160A2 | c.2215+91C>G | Intron (SNP) | VAF 32/165 reads (19%) | catalogued as rs1226626957; called by muse, mutect2, varscan2
- FAM189B | c.-37G>A | 5'UTR (SNP) | VAF 183/183 reads (100%) | called by muse, mutect2, varscan2
- FAM83A | c.*1536G>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- FBXL7 | c.740-1219G>A | Intron (SNP) | VAF 46/109 reads (42%) | called by muse, mutect2, varscan2
- FEZ1 | c.498+124C>A | Intron (SNP) | VAF 24/32 reads (75%) | called by mutect2, varscan2
- FIBIN | c.-156G>A | 5'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- FLRT2 | c.*2994G>A | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- FLVCR1 | c.*1463C>T | 3'UTR (SNP) | VAF 5/23 reads (22%) | catalogued as rs1190289503; called by muse, mutect2
- FMR1 | c.-39C>T | 5'UTR (SNP) | VAF 10/10 reads (100%) | catalogued as COSV99503776; called by muse, mutect2, varscan2
- FN3K | c.591+151C>T | Intron (SNP) | VAF 31/31 reads (100%) | called by muse, mutect2, varscan2
- FOLH1B | n.1832C>T | RNA (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2
- FOXG1 | c.*55G>A | 3'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- FOXL1 | c.*713C>T | 3'UTR (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100206397; called by muse, mutect2, varscan2
- FOXL1 | c.*1610G>C | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- FOXN2 | c.*3814G>A | 3'UTR (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- FSIP1 | c.*2C>T | 3'UTR (SNP) | VAF 216/469 reads (46%) | catalogued as COSV52954005, COSV99527657; called by muse, mutect2, varscan2
- FUT7 | chr9:137034826 G>T | 5'Flank (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- FZD6 | c.177+7522C>G | Intron (SNP) | VAF 60/67 reads (90%) | called by muse, mutect2, varscan2
- GAB1 | chr4:143473646 C>T | 3'Flank (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- GABRB2 | c.*1240G>A | 3'UTR (SNP) | VAF 50/112 reads (45%) | called by mutect2, varscan2
- GALC | c.195+366C>T | Intron (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- GALNT13 | c.*1684C>T | 3'UTR (SNP) | VAF 46/95 reads (48%) | called by muse, varscan2
- GAMT | c.*34C>T | 3'UTR (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- GATB | c.*153C>G | 3'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2
- GBP1 | c.*995G>C | 3'UTR (SNP) | VAF 18/20 reads (90%) | called by muse, mutect2
- GCLC | c.759+596G>A | Intron (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- GLB1L3 | c.1287+109C>T | Intron (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- GLIPR1L1 | c.*332G>T | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- GNA12 | c.526-29390C>T | Intron (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- GOLM1 | c.*1526C>G | 3'UTR (SNP) | VAF 69/123 reads (56%) | called by muse, mutect2, varscan2
- GPAT4 | c.*1079C>T | 3'UTR (SNP) | VAF 62/118 reads (53%) | called by muse, mutect2, varscan2
- GPI | chr19:34365072 C>T | 5'Flank (SNP) | VAF 42/74 reads (57%) | catalogued as rs889711964; called by muse, mutect2, varscan2
- GPR146 | c.*523G>C | 3'UTR (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- GPR158 | c.-1G>A | 5'UTR (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- GPR162 | c.*120G>A | 3'UTR (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- GPR3 | c.*846C>G | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- GPRC5A | c.*4586C>T | 3'UTR (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- GRHL1 | c.1016-41G>C | Intron (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2
- GRIK3 | c.*313C>G | 3'UTR (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- H1-0 | c.-191G>A | 5'UTR (SNP) | VAF 14/26 reads (54%) | catalogued as rs999948546; called by muse, mutect2, varscan2
- HABP2 | c.*64G>T | 3'UTR (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- HACD3 | c.*17G>A | 3'UTR (SNP) | VAF 6/21 reads (29%) | catalogued as rs1422172122; called by muse, mutect2
- HAPLN1 | c.*1363C>T | 3'UTR (SNP) | VAF 50/121 reads (41%) | called by muse, mutect2, varscan2
- HDGFL1 | c.*9G>A | 3'UTR (SNP) | VAF 82/161 reads (51%) | catalogued as rs761228552, COSV100014533; called by muse, mutect2, varscan2
- HECTD1 | c.4982-421G>A | Intron (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- HEPHL1 | c.*1016C>T | 3'UTR (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- HERPUD1 | c.-46C>T | 5'UTR (SNP) | VAF 77/156 reads (49%) | called by muse, mutect2, varscan2
- HERPUD1 | c.*691G>A | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- HESX1 | c.*97T>G | 3'UTR (SNP) | VAF 34/69 reads (49%) | catalogued as rs1315253153; called by muse, mutect2, varscan2
- HLA-DOA | c.*753G>A | 3'UTR (SNP) | VAF 38/172 reads (22%) | called by muse, mutect2, varscan2
- HLA-DPA1 | c.-80C>T | 5'UTR (SNP) | VAF 150/281 reads (53%) | called by muse, mutect2, varscan2
- HLX | c.-189G>A | 5'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.878-22G>C | Intron (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- HOPX | c.-12-124G>A | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- HOXA2 | c.392-41C>G | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- HOXC11 | c.*506C>G | 3'UTR (SNP) | VAF 38/166 reads (23%) | catalogued as COSV99678440; called by muse, mutect2, varscan2
- HSCB | c.236+18G>A | Intron (SNP) | VAF 47/47 reads (100%) | catalogued as rs781643400; called by muse, mutect2, varscan2
- HTR4 | c.*83C>T | 3'UTR (SNP) | VAF 36/195 reads (18%) | catalogued as COSV58790026; called by muse, mutect2, varscan2
- HTR7 | c.*982G>C | 3'UTR (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- IDE | c.*1244G>A | 3'UTR (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-326C>T | Intron (SNP) | VAF 15/215 reads (7%) | catalogued as rs1185317638; called by muse, mutect2
- IGKV2D-26 | c.-4C>T | 5'UTR (SNP) | VAF 5/43 reads (12%) | catalogued as rs1452439313; called by muse, mutect2
- IL10RA | c.*774C>T | 3'UTR (SNP) | VAF 32/235 reads (14%) | called by muse, mutect2, varscan2
- IL22RA2 | c.*62C>T | 3'UTR (SNP) | VAF 16/59 reads (27%) | catalogued as rs770731699; called by muse, mutect2, varscan2
- IL5RA | c.*414C>T | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2
- INF2 | c.701+562C>T | Intron (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- INO80D | c.*9648G>C | 3'UTR (SNP) | VAF 56/118 reads (47%) | called by muse, mutect2, varscan2
- INSIG2 | c.*1234C>T | 3'UTR (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- IRF2BP2 | c.*614G>A | 3'UTR (SNP) | VAF 51/308 reads (17%) | called by muse, mutect2, varscan2
- IRF2BPL | c.-880G>A | 5'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- ISL1 | c.-155G>A | 5'UTR (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- ITGAV | c.*1927G>A | 3'UTR (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- JADE1 | c.1503+1953C>T | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- JPH1 | c.-101G>A | 5'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- JPH3 | c.-63C>T | 5'UTR (SNP) | VAF 102/191 reads (53%) | called by muse, mutect2, varscan2
- KAZN | c.-589G>A | 5'UTR (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- KCNJ5 | chr11:128917060 C>T | 3'Flank (SNP) | VAF 43/164 reads (26%) | called by muse, mutect2, varscan2
- KDM2B | c.*793C>G | 3'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2
- KIAA0930 | c.*4746C>T | 3'UTR (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- KIF17 | c.*246C>A | 3'UTR (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- KIF1C | c.*1235C>G | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- KIF6 | c.*5745G>A | 3'UTR (SNP) | VAF 8/223 reads (4%) | catalogued as rs1420417484; called by muse, mutect2
- KIRREL1 | c.*1171C>T | 3'UTR (SNP) | VAF 37/125 reads (30%) | called by muse, mutect2, varscan2
- KLF5 | c.*1526T>C | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- KLHL8 | c.*1387C>T | 3'UTR (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- KRT6A | c.*278C>T | 3'UTR (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- LAMB1 | c.-42C>T | 5'UTR (SNP) | VAF 60/136 reads (44%) | catalogued as rs1206583645; called by muse, mutect2, varscan2
- LARP6 | c.*172G>C | 3'UTR (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- LCE5A | c.*83C>T | 3'UTR (SNP) | VAF 133/133 reads (100%) | catalogued as COSV100524283; called by muse, varscan2
- LDHC | chr11:18451607 C>G | 3'Flank (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- LEKR1 | c.*463A>G | 3'UTR (SNP) | VAF 120/238 reads (50%) | called by muse, mutect2, varscan2
- LEPR | c.*2144G>A | 3'UTR (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- LGALS17A | n.413G>C | RNA (SNP) | VAF 55/288 reads (19%) | called by muse, mutect2, varscan2
- LINC00518 | n.833C>G | RNA (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- LINC01551 | n.1255-5272C>T | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- LINC01556 | n.278C>T | RNA (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2
- LINC02118 | n.164C>T | RNA (SNP) | VAF 31/192 reads (16%) | called by muse, mutect2, varscan2
- LIX1 | c.483+2132G>A | Intron (SNP) | VAF 14/425 reads (3%) | called by muse, mutect2
- LRP1 | c.1227+33G>A | Intron (SNP) | VAF 66/236 reads (28%) | catalogued as rs1403408014; called by muse, mutect2, varscan2
- LRRC14 | c.*909C>T | 3'UTR (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- LRRC27 | chr10:132376019 G>A | 3'Flank (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- LZTS3 | c.*1533C>G | 3'UTR (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- MAGIX | chrX:49166712 G>A | 3'Flank (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- MAP2K6 | c.366+56C>T | Intron (SNP) | VAF 13/77 reads (17%) | called by mutect2, varscan2
- MAP3K13 | c.*2273C>G | 3'UTR (SNP) | VAF 47/115 reads (41%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+5410G>C | Intron (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
- MAPK8IP1P2 | n.492G>C | RNA (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.*1229G>C | 3'UTR (SNP) | VAF 8/193 reads (4%) | called by muse, mutect2
- MAT1A | c.*701G>C | 3'UTR (SNP) | VAF 38/77 reads (49%) | called by muse, mutect2, varscan2
- MCUR1 | c.-126G>A | 5'UTR (SNP) | VAF 6/17 reads (35%) | catalogued as rs1291985967; called by muse, mutect2, varscan2
- MDGA1 | c.*5188G>T | 3'UTR (SNP) | VAF 97/224 reads (43%) | called by muse, mutect2, varscan2
- MDS2 | n.322C>T | RNA (SNP) | VAF 66/150 reads (44%) | catalogued as rs1342466663; called by muse, varscan2
- MED30 | c.336+19G>A | Intron (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- MESD | c.*1260C>G | 3'UTR (SNP) | VAF 50/106 reads (47%) | catalogued as rs541115159; called by muse, mutect2, varscan2
- MEX3B | c.*899C>G | 3'UTR (SNP) | VAF 14/88 reads (16%) | catalogued as rs923257895; called by muse, mutect2, varscan2
- MFSD14A | c.-91C>G | 5'UTR (SNP) | VAF 26/26 reads (100%) | catalogued as rs1440704214; called by muse, mutect2, varscan2
- MINDY4 | c.1678-15C>T | Intron (SNP) | VAF 51/89 reads (57%) | catalogued as rs1442661420; called by muse, mutect2, varscan2
- MIR29B2 | chr1:207802710 G>C | 5'Flank (SNP) | VAF 19/64 reads (30%) | catalogued as rs1054309479; called by muse, mutect2
- MIR4487 | n.19C>T | RNA (SNP) | VAF 15/31 reads (48%) | called by muse, varscan2
- MIR520D | n.86G>A | RNA (SNP) | VAF 22/67 reads (33%) | catalogued as rs746447038; called by muse, mutect2
- MIRLET7A3 | chr22:46112105 G>C | 5'Flank (SNP) | VAF 32/170 reads (19%) | called by muse, mutect2
- MITF | c.-36C>T | 5'UTR (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- MIXL1 | c.*1051C>T | 3'UTR (SNP) | VAF 7/182 reads (4%) | called by muse, mutect2
- MMACHC | c.*446C>T | 3'UTR (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- MOGS | chr2:74465401 C>T | 5'Flank (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- MSC | c.-54G>A | 5'UTR (SNP) | VAF 10/190 reads (5%) | catalogued as COSV57696178; called by muse, mutect2
- MTHFR | c.*4897C>T | 3'UTR (SNP) | VAF 63/110 reads (57%) | called by muse, mutect2, varscan2
- MTMR8 | c.*261G>C | 3'UTR (SNP) | VAF 41/41 reads (100%) | called by muse, mutect2, varscan2
- MUC20P1 | n.1034G>A | RNA (SNP) | VAF 33/271 reads (12%) | called by muse, mutect2, varscan2
- MUC6 | c.*534G>A | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- MUTYH | c.36+279G>A | Intron (SNP) | VAF 21/218 reads (10%) | called by muse, varscan2
- MYO1C | c.*1049G>A | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- NAPB | c.*1065G>T | 3'UTR (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- NARS1 | c.1384-38G>C | Intron (SNP) | VAF 90/188 reads (48%) | called by muse, mutect2
- NCAPD3 | c.2783-319C>T | Intron (SNP) | VAF 14/71 reads (20%) | catalogued as rs978115119; called by muse, mutect2, varscan2
- NCAPD3 | c.2783-475C>T | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- NDUFA3 | c.*76+12G>A | Intron (SNP) | VAF 17/259 reads (7%) | catalogued as rs987559395; called by muse, mutect2
- NDUFA4 | c.-79C>T | 5'UTR (SNP) | VAF 68/126 reads (54%) | called by muse, mutect2, varscan2
- NDUFA5 | c.*1599G>C | 3'UTR (SNP) | VAF 77/135 reads (57%) | called by muse, mutect2, varscan2
- NDUFC1 | c.-222+931G>C | Intron (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- NEK4 | c.*245G>C | 3'UTR (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- NEUROG2 | c.*437G>A | 3'UTR (SNP) | VAF 67/140 reads (48%) | catalogued as rs990614236; called by muse, mutect2, varscan2
- NFKBIA | c.-10C>T | 5'UTR (SNP) | VAF 24/39 reads (62%) | catalogued as rs760886864; called by muse, mutect2, varscan2
- NKX2-1 | c.*797T>G | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- NKX2-1 | c.*482G>A | 3'UTR (SNP) | VAF 25/64 reads (39%) | catalogued as rs918902794; called by muse, mutect2, varscan2
- NNT | c.1445-1314C>T | Intron (SNP) | VAF 8/114 reads (7%) | catalogued as rs1003148691; called by muse, mutect2
- NOP9 | c.*2887C>T | 3'UTR (SNP) | VAF 49/85 reads (58%) | called by muse, mutect2, varscan2
- NOS1AP | c.*447C>T | 3'UTR (SNP) | VAF 65/352 reads (18%) | called by muse, mutect2, varscan2
- NR1D1 | c.-420C>T | 5'UTR (SNP) | VAF 67/127 reads (53%) | called by muse, mutect2, varscan2
- NR2E1 | c.-257C>T | 5'UTR (SNP) | VAF 71/139 reads (51%) | called by muse, mutect2, varscan2
- NSD2 | c.1881+4136G>A | Intron (SNP) | VAF 37/95 reads (39%) | called by muse, mutect2, varscan2
- NTNG2 | c.1223-79G>T | Intron (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- NUBP2 | c.-53G>A | 5'UTR (SNP) | VAF 25/122 reads (20%) | catalogued as rs1266597715, COSV51907231; called by muse, mutect2, varscan2
- NUMB | chr14:73275203 C>T | 3'Flank (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- NUS1 | c.*1794C>G | 3'UTR (SNP) | VAF 70/134 reads (52%) | called by muse, mutect2, varscan2
- OLIG1 | c.*1006G>T | 3'UTR (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- OR8H1 | c.-25C>T | 5'UTR (SNP) | VAF 160/342 reads (47%) | catalogued as rs779324381; called by muse, mutect2, varscan2
- OR9Q1 | c.*409T>G | 3'UTR (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- OSBPL7 | c.-87-11C>G | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- OTULINL | c.*2044G>A | 3'UTR (SNP) | VAF 50/97 reads (52%) | catalogued as rs1441566312; called by muse, mutect2, varscan2
- P2RY13 | c.*157G>T | 3'UTR (SNP) | VAF 52/101 reads (51%) | catalogued as rs192372273; called by muse, mutect2, varscan2
- P4HB | c.*714G>C | 3'UTR (SNP) | VAF 50/52 reads (96%) | called by muse, mutect2, varscan2
- PACSIN1 | c.*1420G>A | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- PAICS | c.-51-29G>A | Intron (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- PAK6 | c.*549C>T | 3'UTR (SNP) | VAF 44/93 reads (47%) | catalogued as COSV53046761; called by muse, mutect2, varscan2
- PAPLN | c.171-45G>T | Intron (SNP) | VAF 70/124 reads (56%) | called by muse, mutect2, varscan2
- PARVA | c.798+38A>G | Intron (SNP) | VAF 127/272 reads (47%) | called by muse, mutect2, varscan2
- PAX2 | c.-167_-148del | 5'UTR (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel, varscan2
- PAX9 | c.*201G>A | 3'UTR (SNP) | VAF 52/103 reads (50%) | called by muse, mutect2, varscan2
- PCDHB7 | c.*894G>A | 3'UTR (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- PDCD6IP | c.-20C>T | 5'UTR (SNP) | VAF 43/94 reads (46%) | called by muse, varscan2
- PEG10 | c.*2038G>C | 3'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- PENK | c.139-1831G>A | Intron (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- PEX26 | c.*1125C>G | 3'UTR (SNP) | VAF 39/40 reads (98%) | catalogued as rs1169221037; called by muse, mutect2, varscan2
- PFKFB2 | chr1:207079563 C>G | 3'Flank (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- PGGHG | c.*1270C>T | 3'UTR (SNP) | VAF 29/58 reads (50%) | catalogued as rs1298758632; called by muse, mutect2, varscan2
- PGGT1B | c.*1538C>T | 3'UTR (SNP) | VAF 82/183 reads (45%) | catalogued as rs890352189; called by muse, mutect2, varscan2
- PHPT1 | chr9:136849257 G>A | 5'Flank (SNP) | VAF 26/108 reads (24%) | called by muse, varscan2
- PIDD1 | c.296-61G>C | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- PIK3C2G | c.-19C>T | 5'UTR (SNP) | VAF 28/320 reads (9%) | catalogued as rs769600949; called by muse, mutect2
- PIK3C3 | c.*5910C>T | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- PLA2G4E | c.*557C>T | 3'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*6498G>A | 3'UTR (SNP) | VAF 32/56 reads (57%) | catalogued as rs1016556818; called by muse, mutect2, varscan2
- PLPP3 | c.-196G>C | 5'UTR (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- PLPP5 | c.635-221G>C | Intron (SNP) | VAF 110/258 reads (43%) | called by muse, varscan2
- POLE2 | c.*39C>T | 3'UTR (SNP) | VAF 36/207 reads (17%) | called by muse, mutect2, varscan2
- POLR3E | c.-38-17C>G | Intron (SNP) | VAF 92/212 reads (43%) | called by muse, mutect2, varscan2
- POU6F1 | chr12:51188347 G>C | 3'Flank (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- PPHLN1 | c.1024+379C>T | Intron (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- PPIE | c.31+184C>T | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- PPP1R12B | c.*6162G>A | 3'UTR (SNP) | VAF 37/130 reads (28%) | called by muse, mutect2, varscan2
- PPP1R9A | c.*3825G>A | 3'UTR (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- PRADC1 | c.-56A>T | 5'UTR (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- PRR18 | c.*1070_*1071insTT | 3'UTR (INS) | VAF 18/64 reads (28%) | called by pindel, varscan2
- PRR23A | c.*958G>A | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- PRRC1 | c.1128+722C>T | Intron (SNP) | VAF 56/110 reads (51%) | called by muse, mutect2, varscan2
- PRRX1 | chr1:170663233 C>T | 5'Flank (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.839-105G>A | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- PTAR1 | c.*3683G>A | 3'UTR (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- PTPRB | c.*11G>A | 3'UTR (SNP) | VAF 13/208 reads (6%) | catalogued as rs1290815018; called by muse, mutect2
- PTPRD | c.*370G>A | 3'UTR (SNP) | VAF 33/76 reads (43%) | catalogued as rs990083213, COSV100645962; called by muse, mutect2, varscan2
- PTPRK | c.*51G>A | 3'UTR (SNP) | VAF 171/743 reads (23%) | called by muse, mutect2, varscan2
- PUM2 | c.*2693C>G | 3'UTR (SNP) | VAF 80/147 reads (54%) | called by muse, mutect2, varscan2
- PXN | c.*335C>A | 3'UTR (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- PYGO1 | c.*797G>A | 3'UTR (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- RAB6B | c.*3688C>T | 3'UTR (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- RAD21 | c.1470+292C>T | Intron (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
151 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 151 other) are not listed here.
